Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9O7, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9O7-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Lymph nodes, right pelvic, dissection: No tumor identified in eight (0/8).
- B. Lymph nodes, left pelvic, dissection: No tumor identified in seven (0/7).
- C. Prostate gland, seminal vesicles, radical prostatectomy:
1. Prostatic adenocarcinoma, Gleason grade 5+5=10; see comment.
2. Extraprostatic tumor present.
3. Tumor present at multiple inked resection margins; see comment.
4. Seminal vesicles free of tumor.
- D. Fascia, biopsy: vascular fibroadipose tissue, no tumor.

COMMENT:

Synoptic Comment for Prostate Tumors

1. Type of tumor: Small acinar adenocarcinoma.
2. Location of tumor: Bilateral anterior, apex to base (slides C2-C7, C17-C21), extending posteriorly on the left, apex to base (C15-C16), and posteriorly on the right base (C12) and at the right apex (C9).
3. Estimated volume of tumor: $4.7 \times 4 \times 1.8 = 33$ cc.
4. Gleason score: 5+5=10.
5. Estimated volume > Gleason pattern 3: 100%.
6. Involvement of capsule: Tumor invades capsule at multiple locations.
7. Extraprostatic extension: Present but limited in extent, at the left posterior-lateral base (Slides C16) and the anterior base near the bladder margin (slides C22, and C23). Tumor also present in skeletal muscle of anterior apex-midgland suspicious for extracapsular tumor (slide C18).
8. Status of excision margins for tumor: Tumor extends to inked excision margins in multiple locations anteriorly bilaterally, predominantly apex and midgland (slides C2-C5, C7, C17-C19). Additionally, there is cauterized tumor present at the inked left posterior base margin in the permanent sections from the frozen section remnant (slide C1). The frozen section slides were reviewed and confirm that no tumor is seen in

ICD-O 3

Adenocarcinoma NOS 8140/3
Site: Prostate C61.9
JCO 3/27/14

[page 2 of 3]
these sections. [REDACTED] has reviewed slide C1 and agrees.

9. Involvement of seminal vesicle: No tumor.
10. Perineural infiltration: Present (e.g. slides C2, C3, C4, C5, C6, C7).
11. Prostatic intraepithelial neoplasia (PIN): Not identified.
12. AJCC/UICC stage: pT3aN0MX R1.
13. Additional comments: Vascular invasion is identified (slide C23). Tumor is present in skeletal muscle in the anterior mid prostate (C18), which is suspicious for extraprostatic extension in this location.

Specimen(s) Received

A: Right pelvic lymph nodes (fresh)
B: Left pelvic lymph nodes (fresh)
C: Prostate & Seminal Vesicles (FS)
D: Fascia

Intraoperative Diagnosis

FS1 (C) Prostate, left posterior bladder margin, radical prostatectomy: No tumor seen, thrombus noted.
[REDACTED]

Clinical History

The patient is a [REDACTED] with a history of prostate cancer, Gleason grade 5+4 (9), who undergoes radical retropubic, nerve-sparing prostatectomy with bilateral pelvic lymph node dissections.

Gross Description

The specimen is received fresh in four parts, each labeled with the patient's name and unit number.

Part A, additionally labeled "right pelvic lymph nodes," consists of multiple aggregates of soft, red-yellow, fibrofatty tissue measuring 7 x 3 x 1 cm in greatest dimension. Cassettes are submitted as follows:

Cassette A1: Right lymph node, bisected.
Cassette A2: One lymph node candidate.
Cassette A3: Multiple lymph node candidates.

Part B, additionally labeled "left pelvic nodes," consists of multiple aggregates of soft, red-yellow, fibrofatty tissue measuring in maximum dimension 6 x 3 x 0.8 cm. Cassettes are submitted as follows:

Cassette B1: Multiple lymph node candidates.
Cassette B2: One lymph node candidate.

Part C (FS1), labeled "prostate and seminal vesicles (FS)," consists of a large, intact prostate gland with attached seminal vesicle/vas deferens bundles weighing 55.1 gm. The gland measures, in maximum dimension, 4 cm from apex to base, 4.7 cm from medial to lateral and 3.8 cm from anterior to posterior. The exterior of the gland is rough and red-tan, with numerous sutures along the anterior midline, closing the dorsal vein complex. Sutures are also noted at the left posterior bladder margin, designating the site requested for frozen section. Firm, white-tan, ovoid calculi are noted bilaterally along the lateral aspect of the prostate, just underlying the most exterior fascia. The largest of the calculi measures 0.7 cm in greatest dimension. There are numerous firm, palpable nodules within the prostate noted bilaterally. The right anterior surface of the gland is inked in green, the left anterior surface is inked in blue, and the posterior surface is inked in black. A shave biopsy is taken from the left posterior bladder margin, bread-loafed, and submitted for frozen section diagnosis 1. Following frozen section, the apical and remaining bladder margins are removed and fixed separately, and the remainder of the gland is serially sectioned from apex to base perpendicular to the urethral channel into five serial slices. The serial slices reveal a large, tan to bright white, firm, solid, lobulated lesion dominating the left lobe and crossing over into the right lobe along the anterior aspect. This lesion essentially replaces most of the central and transitional zones in all five serial slices. A small aspect of relatively normal-appearing tissue is noted in the right posterior quadrant of serial slices 1-4. This area is composed of much softer, semi-porous, light tan tissue. Following further dissection and submission of tissue for pathologic evaluation, all of the remnant fresh prostatic tissue is taken for tissue banking/research purposes. The apical and bladder margins, as well as representative sections of prostate and representative portions of the seminal vesicle/vas deferens bundles are submitted as follows:

Cassette C1 (FS1): Left posterior base.

[page 3 of 3]
Apical Margin

Cassette C2: Right apex, 12 - 6 o'clock, bread-loafed and entirely submitted.
Cassette C3: Left apex, 6 - 12 o'clock, bread-loafed and entirely submitted.

Right anterior quadrant

Cassette C4: Serial slice 1.
Cassette C5: Serial slice 2.
Cassette C6: Serial slice 3.
Cassette C7: Serial slice 4.
Cassette C8: Serial slice 5.

Right posterior quadrant

Cassette C9: Serial slice 1.
Cassette C10: Serial slice 2.
Cassette C11: Serial slice 3.
Cassette C12: Serial slice 4.

Left posterior quadrant

Cassette C13: Serial slice 1.
Cassette C14: Serial slice 2.
Cassette C15: Serial slice 3.
Cassette C16: Serial slice 4.

Left anterior quadrant

Cassette C17: Serial slice 1.
Cassette C18: Serial slice 2.
Cassette C19: Serial slice 3.
Cassette C20: Serial slice 4.
Cassette C21: Serial slice 5.

Bladder margin

Cassette C22: Right bladder margin, bread-loafed and entirely submitted.
Cassette C23: Left bladder margin, bread-loafed and entirely submitted.

Prostatic/Seminal vesicle junction

Cassette C24: Right seminal vesicle and cross-section of vas deferens.
Cassette C25: Left seminal vesicle and cross-section of vas deferens.

Part D, additionally labeled "4 - fascia," consists of two soft, pink-tan, unoriented tissue fragments measuring 1.9 x 1.5 x 0.3 cm in aggregate. The specimen is transected and entirely submitted in cassette D1.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed out on [REDACTED]

Source: NCI Genomic Data Commons file 365929f1-3ecd-49c4-9adf-1fab2d2772f3 (TCGA-V1-A9O7.0D2327CA-DE0A-4B74-BD53-6370ED222B96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).